Somatic mutation profile of tumor specimen 0DHY47 from CCDI case PANLMU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive.
Specimen 0DHY47: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2dd9783e-043d-4bee-a6fa-753343180f09.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHY31 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48dff5a9-8b07-4299-87cb-0f10913f90d3

The open-access MAF lists 47 somatic variants for this specimen: 31 protein-altering or splice-affecting, 6 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Intron 10, Silent 6, Splice Region 3, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATG2A | c.3478G>T p.D1160Y | Missense Mutation (SNP) | VAF 61/168 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV65968383; called by muse, mutect2, varscan2
- ERBB4 | c.3687G>A p.M1229I | Missense Mutation (SNP) | VAF 240/547 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV61463375; called by muse, mutect2, varscan2
- FRMPD4 | c.2003C>A p.T668N | Missense Mutation (SNP) | VAF 87/192 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs376545795; ClinVar: benign; called by muse, mutect2, varscan2
- MTM1 | c.590C>G p.T197S | Missense Mutation (SNP) | VAF 253/656 reads (39%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.447); catalogued as HM971495; called by muse, mutect2, varscan2
- RPL13A | c.171C>G p.F57L | Missense Mutation (SNP) | VAF 69/218 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as COSV52619549; called by muse, mutect2, varscan2
- RPS6KA2 | c.1952A>T p.K651M | Missense Mutation (SNP) | VAF 162/428 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.648); catalogued as COSV55818769; called by muse, mutect2, varscan2
- SLC15A5 | c.664C>T p.L222F | Missense Mutation (SNP) | VAF 53/614 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.144); catalogued as rs867254815; called by muse, mutect2
- SRRM3 | c.1898G>T p.S633I | Missense Mutation (SNP) | VAF 107/251 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100418606; called by muse, mutect2, varscan2
- UBR2 | c.2750C>T p.S917L | Missense Mutation (SNP) | VAF 185/427 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs754681331, COSV65749237; called by muse, mutect2, varscan2
- ZNF337 | c.2060G>A p.C687Y | Missense Mutation (SNP) | VAF 190/460 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs771755693; called by muse, mutect2, varscan2
- ALG1L | c.450G>T p.Q150H | Missense Mutation (SNP) | VAF 169/408 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 25/818 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- C1QC | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 116/288 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAND1 | c.2260G>T p.A754S | Missense Mutation (SNP) | VAF 145/404 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- CHAF1B | c.1061+1G>T p.X354_splice | Splice Site (SNP) | VAF 158/359 reads (44%) | called by muse, mutect2, varscan2
- CMTM5 | c.442T>G p.L148V | Missense Mutation (SNP) | VAF 102/271 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CUL4B | c.1647A>C p.E549D | Missense Mutation (SNP) | VAF 62/577 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- DOCK1 | c.3506C>G p.T1169S | Missense Mutation (SNP) | VAF 243/612 reads (40%) | SIFT tolerated (0.74); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DPF3 | c.1038A>C p.L346F | Missense Mutation (SNP) | VAF 121/331 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAT2 | c.6784G>T p.V2262L | Missense Mutation (SNP) | VAF 153/367 reads (42%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- IFNA4 | c.254_255del p.Q85Pfs*26 | Frame Shift Del (DEL) | VAF 120/320 reads (38%) | called by mutect2, varscan2
- KHNYN | c.-17G>C | Splice Region (SNP) | VAF 55/153 reads (36%) | called by muse, mutect2, varscan2
- PKN1 | c.1278A>T p.A426= | Splice Region (SNP) | VAF 114/178 reads (64%) | called by mutect2, varscan2
- PLK3 | c.1379C>A p.P460H | Missense Mutation (SNP) | VAF 103/382 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SIGLEC16 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 81/257 reads (32%) | called by muse, mutect2, varscan2
- SPEN | c.10867G>T p.A3623S | Missense Mutation (SNP) | VAF 110/263 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- TAT | c.1224+5G>C | Splice Region (SNP) | VAF 106/270 reads (39%) | called by muse, mutect2, varscan2
- TLL1 | c.1148C>G p.P383R | Missense Mutation (SNP) | VAF 186/438 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- WDR24 | c.1060G>A p.A354T (on ENST00000248142; = p.A224T on NM_032259.4) | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- ZNF143 | c.1128C>A p.N376K | Missense Mutation (SNP) | VAF 103/288 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ZNF226 | c.743G>C p.G248A | Missense Mutation (SNP) | VAF 136/444 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- ADD2 | c.624C>T p.G208= | Silent (SNP) | VAF 154/325 reads (47%) | catalogued as rs147916626; called by muse, mutect2, varscan2
- APLNR | c.981C>A p.G327= | Silent (SNP) | VAF 121/285 reads (42%) | called by muse, mutect2, varscan2
- HSPG2 | c.2610G>A p.R870= | Silent (SNP) | VAF 53/157 reads (34%) | called by muse, mutect2, varscan2
- LANCL3 | c.153C>A p.A51= | Silent (SNP) | VAF 10/192 reads (5%) | called by muse, mutect2
- SDCCAG8 | c.897T>C p.N299= | Silent (SNP) | VAF 202/517 reads (39%) | called by muse, mutect2, varscan2
- STAT6 | c.963G>A p.A321= | Silent (SNP) | VAF 116/281 reads (41%) | catalogued as rs759578006, COSV100273467; called by muse, mutect2, varscan2
- FAM193A | c.2404-86A>G | Intron (SNP) | VAF 11/19 reads (58%) | catalogued as rs1019343083; called by muse, mutect2, varscan2
- KANK4 | c.1901-35A>G | Intron (SNP) | VAF 107/295 reads (36%) | catalogued as rs1183415562; called by muse, mutect2, varscan2
- LARS1 | c.1655+60_1656-51del | Intron (DEL) | VAF 94/293 reads (32%) | called by mutect2, varscan2
- LIG3 | c.1041+91G>T | Intron (SNP) | VAF 22/66 reads (33%) | called by muse, mutect2, varscan2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 5/35 reads (14%) | called by muse, varscan2
- NIT2 | c.584+83C>T | Intron (SNP) | VAF 24/66 reads (36%) | called by muse, mutect2, varscan2
- PHACTR1 | c.251-39564C>T | Intron (SNP) | VAF 8/12 reads (67%) | catalogued as rs926395157; called by mutect2, varscan2
- PTPRC | c.3331-54A>G | Intron (SNP) | VAF 48/103 reads (47%) | called by muse, mutect2, varscan2
- TEPP | c.688-26G>C | Intron (SNP) | VAF 79/238 reads (33%) | catalogued as COSV52043399; called by muse, mutect2, varscan2
- WDR27 | c.1402+358C>A | Intron (SNP) | VAF 146/367 reads (40%) | called by muse, mutect2, varscan2
